Gene-level copy-number profile of tumor specimen C3L-04212-05 from CPTAC case C3L-04212, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 76.5 years (27,946 days).
Specimen C3L-04212-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Skin; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 5debedb6-c5b5-48dc-bd86-7fa7d84d3a77.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-04212-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,225 have no estimate.
https://portal.gdc.cancer.gov/files/3af79eef-0b21-4be4-8527-a15fad832347

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 1: 7,626; copy number 2: 39,245; copy number 3: 11,494; copy number 4: 28; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:109,984,858–109,986,565, 1 gene: AL355974.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:66,432,486–66,518,524, 1 gene, copy number 5 (within-gene range 4–5): AC009879.3.
- chr8:66,480,648–66,518,524, 3 genes, copy number 5: AC009879.1, VXN, RNU6-1324P.

Autosomal genes at a single copy (total copy number 1): 7,626. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
